Somatic mutation profile of tumor specimen TCGA-XF-A9SJ-01A (aliquot TCGA-XF-A9SJ-01A-11D-A391-08) from TCGA case TCGA-XF-A9SJ, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 83.1 years (30,362 days).
Specimen TCGA-XF-A9SJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0d65510-9ce5-4808-9165-b2cc14826d23.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XF-A9SJ-10A (Blood Derived Normal), aliquot TCGA-XF-A9SJ-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e9c4b9d8-c4da-4431-9434-ff0feaaa0886

The open-access MAF lists 308 somatic variants for this specimen: 220 protein-altering or splice-affecting, 79 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 188, Silent 79, Nonsense Mutation 18, Splice Region 5, RNA 4, Intron 3, Splice Site 3, 5'Flank 2, Frame Shift Del 2, Translation Start Site 2, Nonstop Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAN | c.4421G>A p.G1474E | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.327); catalogued as COSV100719371; called by muse, mutect2, varscan2
- ACAT1 | c.386G>A p.G129E | Missense Mutation (SNP) | VAF 5/101 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99759449; called by muse, mutect2
- ACIN1 | c.2102C>T p.S701L | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.107); catalogued as COSV99400428; called by muse, mutect2, varscan2
- ACSM4 | c.788C>G p.S263* | Nonsense Mutation (SNP) | VAF 5/50 reads (10%) | catalogued as COSV101257290; called by muse, mutect2
- ADAR | c.2376G>C p.L792F | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99426819; called by muse, mutect2, varscan2
- ADORA2B | c.177C>A p.F59L | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1429176924, COSV100420068; called by muse, mutect2, varscan2
- AFF1 | c.1427A>C p.D476A | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.763); catalogued as COSV100321110; called by muse, mutect2, varscan2
- AGBL5 | c.1600G>A p.D534N | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100549463; called by muse, mutect2, varscan2
- ALG11 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.012); catalogued as COSV101584396; called by muse, mutect2, varscan2
- ALS2 | c.1430G>A p.G477E | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); catalogued as COSV99970125; called by muse, mutect2
- AMER3 | c.359C>T p.S120F | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.438); catalogued as COSV58466914; called by muse, mutect2
- ANKRD45 | c.258G>A p.M86I | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.191); catalogued as COSV100322701; called by muse, mutect2
- ANLN | c.1870-1G>A p.X624_splice | Splice Site (SNP) | VAF 6/44 reads (14%) | catalogued as COSV99732931; called by muse, mutect2, varscan2
- APOC1 | c.231G>C p.E77D | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV99377249; called by muse, mutect2
- ASIC1 | c.1521G>C p.M507I | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as COSV57319648, COSV99948289; called by muse, mutect2
- ATP6V1B1 | c.790G>T p.E264* | Nonsense Mutation (SNP) | VAF 18/46 reads (39%) | catalogued as rs200839517, COSV52269890, COSV99314546; called by muse, mutect2, varscan2
- BLOC1S2 | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.602); catalogued as rs1564875582, COSV100559467; called by muse, mutect2, varscan2
- BRPF3 | c.688C>T p.L230F | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100326227; called by muse, mutect2
- BRWD1 | c.609+1G>C p.X203_splice | Splice Site (SNP) | VAF 46/74 reads (62%) | catalogued as COSV100314247; called by muse, mutect2, varscan2
- C15orf39 | c.122G>A p.C41Y | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.726); catalogued as rs150862421; called by mutect2, varscan2
- CACNA1A | c.5368G>A p.E1790K | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as COSV100803311; called by muse, mutect2
- CALB1 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55367917; called by muse, mutect2
- CAPN11 | c.1392G>T p.Q464H | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs751377623, COSV101291961; called by muse, mutect2, varscan2
- CCDC59 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.099); catalogued as COSV99810842; called by muse, mutect2, varscan2
- CCDC96 | c.776G>A p.R259K | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1463534779, COSV100028125; called by muse, mutect2, varscan2
- CCDC97 | c.29C>G p.A10G | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.03); catalogued as COSV99523873; called by muse, mutect2
- CEBPG | c.193T>C p.Y65H | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV99392893; called by muse, mutect2
- CFAP47 | c.2093G>C p.R698T | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.58); PolyPhen benign (0.012); catalogued as COSV52888200, COSV52891034; called by muse, mutect2, varscan2
- CFAP57 | c.1658A>C p.K553T | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.481); catalogued as COSV100994117; called by muse, mutect2
- CFAP70 | c.364C>T p.Q122* | Nonsense Mutation (SNP) | VAF 5/40 reads (13%) | catalogued as COSV100161101; called by muse, mutect2, varscan2
- CHP1 | c.136C>G p.L46V | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); catalogued as COSV100587192; called by muse, mutect2, varscan2
- CHRNE | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.184); catalogued as rs866487633, COSV53419346; called by muse, mutect2
- CLEC18B | c.459C>T p.L153= | Splice Region (SNP) | VAF 14/68 reads (21%) | catalogued as rs546829879, COSV100375806; called by muse, varscan2
- CNGA3 | c.1756G>C p.E586Q | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.226); catalogued as COSV99737581; called by muse, mutect2
- CNTNAP1 | c.1283G>A p.R428Q | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.138); catalogued as rs868749538, COSV52847713; called by muse, mutect2
- CORO7 | c.2050G>A p.G684R | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200575254, COSV52027812, COSV99228192; called by muse, mutect2, varscan2
- CPA5 | c.854G>A p.S285N | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as rs1554408687, COSV62569250; called by muse, mutect2
- CRIM1 | c.2692G>A p.E898K | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.057); catalogued as COSV99754628; called by muse, mutect2, varscan2
- CSMD3 | c.5880C>G p.D1960E (on ENST00000297405 / NM_001363185.1; = p.D1856E on NM_052900.3) | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.087); catalogued as COSV99849255; called by muse, mutect2, varscan2
- CSNK1G2 | c.923T>C p.L308P | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); catalogued as rs1464891033, COSV99730274; called by muse, mutect2, varscan2
- CUTC | c.425T>G p.V142G | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as COSV100976189; called by muse, mutect2, varscan2
- CYP20A1 | c.499C>T p.H167Y | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.718); catalogued as COSV100619145; called by muse, mutect2, varscan2
- DAP | c.136G>C p.E46Q | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as COSV99136443; called by muse, mutect2
- DDI2 | c.375A>G p.I125M | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100197916; called by muse, mutect2
- DENND4A | c.4951T>G p.L1651V | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101475447; called by muse, mutect2, varscan2
- DMAC1 | c.41C>T p.T14I | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as rs781137305, COSV100830335; called by muse, mutect2, varscan2
- DMXL2 | c.7607T>C p.L2536P | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99198695; called by muse, mutect2, varscan2
- DNAH8 | c.12650G>C p.R4217P | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100547316, COSV100547739; called by muse, mutect2, varscan2
- DNAJB2 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs771292719, COSV100339166; called by muse, mutect2, varscan2
- DSN1 | c.790C>G p.Q264E | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV101041118; called by muse, mutect2
- DST | c.3856G>A p.E1286K (on ENST00000361203 / NM_001374722.1; = p.E960K on NM_001723.6) | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as COSV55033750; called by muse, mutect2
- EIF2B4 | c.561C>A p.S187R (on ENST00000347454 / NM_001034116.2; = p.S186R on NM_015636.3) | Missense Mutation (SNP) | VAF 4/65 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.052); catalogued as rs1256574955, COSV99278035; called by muse, mutect2
- EIF3I | c.472G>A p.G158R | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs1420091879, COSV100557321; called by muse, mutect2, varscan2
- ELMO1 | c.178T>C p.Y60H | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100166276; called by muse, mutect2, varscan2
- ELN | c.1415G>A p.G472E | Missense Mutation (SNP) | VAF 28/171 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99333247; called by muse, mutect2, varscan2
- ERCC2 | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as COSV55538474, COSV55543462, COSV99676436; called by muse, mutect2, varscan2
- ERCC6L | c.814G>C p.D272H | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100559284; called by muse, mutect2, varscan2
- ERN2 | c.349T>C p.C117R | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99892507; called by muse, mutect2, varscan2
- FAT3 | c.49T>C p.C17R | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs1408833323, COSV99971558; called by muse, mutect2, varscan2
- FAT3 | c.6022G>A p.G2008R | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99971561; called by muse, mutect2, varscan2
- FBN2 | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.348); catalogued as COSV99330995; called by muse, mutect2, varscan2
- FLACC1 | c.359G>C p.R120T | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.023); catalogued as COSV99630951; called by muse, mutect2, varscan2
- FLT3LG | c.268G>C p.A90P | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99201367; called by muse, varscan2
- FNDC3A | c.529G>A p.E177K (on ENST00000492622 / NM_001079673.2; = p.E121K on NM_014923.5) | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.075); catalogued as COSV101001369, COSV65695233; called by muse, mutect2, varscan2
- FOXR2 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as COSV59258934; called by muse, mutect2
- GOLGA1 | c.218G>C p.R73T | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.057); catalogued as COSV101002609; called by muse, mutect2, varscan2
- GON4L | c.6205G>A p.G2069R | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.019); catalogued as rs1199565772, COSV55198270; called by muse, mutect2, varscan2
- GPR15 | c.862G>A p.G288R | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); catalogued as COSV99423971; called by muse, mutect2, varscan2
- GRM8 | c.2661G>C p.E887D | Missense Mutation (SNP) | VAF 6/139 reads (4%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.956); catalogued as rs1433799273, COSV100286373; called by muse, mutect2
- GYS1 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 34/184 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs1269744178, COSV99621252; called by muse, mutect2, varscan2
- H3C6 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.323); catalogued as COSV64519400, COSV64519670; called by muse, mutect2, varscan2
- HAPLN2 | c.578G>A p.W193* | Nonsense Mutation (SNP) | VAF 5/25 reads (20%) | catalogued as COSV54815729, COSV99661051; called by muse, mutect2
- HELB | c.2165C>T p.S722F | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs1471790195, COSV99922253; called by muse, mutect2, varscan2
- HMCN1 | c.848C>T p.S283F | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99636538; called by muse, mutect2, varscan2
- IGSF10 | c.6917C>T p.S2306L | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs997640867, COSV99196550; called by muse, mutect2
- IL1RAPL1 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.026); catalogued as COSV100150966; called by muse, mutect2
- IL6ST | c.1030T>C p.Y344H | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100411082; called by muse, mutect2
- INCENP | c.1180G>C p.E394Q | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV99611664; called by muse, mutect2
- IPO8 | c.2311C>T p.R771* | Nonsense Mutation (SNP) | VAF 9/68 reads (13%) | catalogued as rs775413184, COSV56239939; called by muse, mutect2, varscan2
- IQCG | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.668); catalogued as rs1159649096, COSV99502767; called by muse, mutect2
- JAML | c.110C>T p.S37L (on ENST00000356289 / NM_001098526.2; = p.S27L on NM_153206.3) | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV99409775; called by muse, mutect2
- JUP | c.1348G>A p.D450N | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs782165604, COSV100159841; called by muse, mutect2
- KANSL1 | c.628C>T p.L210F | Missense Mutation (SNP) | VAF 8/224 reads (4%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV52272425; called by muse, mutect2
- KCNA2 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as COSV100316139; called by muse, mutect2, varscan2
- KCNE2 | c.65A>C p.Y22S | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99285813; called by muse, mutect2
- KCNJ16 | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.876); catalogued as COSV52255351; called by muse, mutect2, varscan2
- KCNU1 | c.3388G>A p.E1130K | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as COSV67757646, COSV67758481; called by muse, mutect2, varscan2
- KDM6A | c.1400G>A p.W467* | Nonsense Mutation (SNP) | VAF 5/9 reads (56%) | catalogued as COSV100938656; called by muse, mutect2, varscan2
- KRI1 | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV57264175; called by muse, mutect2
- LCMT2 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs761343841, COSV99980273; called by muse, varscan2
- LMLN | c.59C>T p.S20L | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV99502407, COSV99502768; called by muse, mutect2, varscan2
- LMO7 | c.3438G>C p.Q1146H (on ENST00000357063; = p.Q827H on NM_005358.5) | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.042); catalogued as rs1453445524, COSV100413900; called by muse, mutect2, varscan2
- LRRC27 | c.894G>C p.E298D | Missense Mutation (SNP) | VAF 53/100 reads (53%) | SIFT tolerated (0.29); PolyPhen benign (0.121); catalogued as COSV100689988; called by muse, mutect2, varscan2
- LRRC73 | c.76C>A p.R26S | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as COSV99447606; called by muse, mutect2
- MAPK8IP3 | c.1066G>C p.E356Q | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.248); catalogued as COSV99169809; called by muse, mutect2
- MASP1 | c.1603G>A p.V535I | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.037); catalogued as rs148698841, COSV100537655; called by muse, mutect2
- MEGF8 | c.6847G>A p.E2283K (on ENST00000251268 / NM_001271938.2; = p.E2216K on NM_001410.3) | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV52104530; called by muse, mutect2
- MICAL2 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99818446; called by muse, mutect2
- MIOS | c.1701G>C p.E567D | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.62); PolyPhen benign (0.062); catalogued as COSV100402975; called by muse, mutect2
- MLKL | c.118A>G p.K40E | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV100087505; called by muse, mutect2, varscan2
- MPND | c.1288G>T p.E430* | Nonsense Mutation (SNP) | VAF 8/42 reads (19%) | catalogued as COSV99515420; called by muse, mutect2, varscan2
- MRNIP | c.213C>A p.L71= | Splice Region (SNP) | VAF 16/107 reads (15%) | catalogued as COSV99481804; called by muse, mutect2, varscan2
- MRPL58 | c.376A>T p.K126* | Nonsense Mutation (SNP) | VAF 4/48 reads (8%) | catalogued as COSV100043061; called by muse, mutect2
- MSL2 | c.745A>G p.T249A | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs1200214675, COSV99388304; called by muse, mutect2
- MTA3 | c.199G>T p.E67* | Nonsense Mutation (SNP) | VAF 3/28 reads (11%) | catalogued as COSV101290750; called by muse, mutect2
- MUC13 | c.224G>C p.S75T | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT tolerated (0.84); PolyPhen benign (0.012); catalogued as COSV100222517; called by muse, mutect2, varscan2
- MX1 | c.1544G>A p.R515K | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs1238855005, COSV99912882; called by muse, mutect2, varscan2
- MYO7B | c.6007C>T p.R2003W | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs753292445, COSV100265048; called by muse, mutect2, varscan2
- N4BP2 | c.832C>G p.Q278E | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV99789334; called by muse, mutect2, varscan2
- NAGS | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs771540094, CM167134, COSV99243765; called by muse, mutect2, varscan2
- NATD1 | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV101204724; called by muse, mutect2, varscan2
- NBPF11 | c.1684G>A p.D562N | Missense Mutation (SNP) | VAF 18/330 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs1253518403; called by muse, mutect2
- NEB | c.9774G>C p.L3258F | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as COSV99428462; called by muse, mutect2, varscan2
- NIBAN3 | c.1770G>C p.K590N | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.326); catalogued as COSV99962791; called by muse, mutect2, varscan2
- NOP9 | c.1706G>A p.W569* | Nonsense Mutation (SNP) | VAF 5/48 reads (10%) | catalogued as rs991218013, COSV51866383, COSV99351212; called by muse, mutect2, varscan2
- NPHS2 | c.928G>C p.E310Q | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); catalogued as CM1010082, COSV100858215; called by muse, mutect2
- NSD3 | c.2122G>C p.E708Q | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100388966; called by muse, mutect2
- NSUN7 | c.259C>T p.Q87* | Nonsense Mutation (SNP) | VAF 8/65 reads (12%) | catalogued as COSV57273433; called by muse, mutect2, varscan2
- NTRK2 | c.563A>C p.N188T | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV99458906; called by muse, mutect2, varscan2
- NUP50 | c.1042G>A p.V348I | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as COSV100754422; called by muse, mutect2, varscan2
- OBI1 | c.508A>G p.I170V | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.046); catalogued as rs1275630490, COSV99932646; called by muse, mutect2, varscan2
- OR51F2 | c.983T>C p.I328T | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV100438171; called by muse, mutect2, varscan2
- OR5D14 | c.469G>T p.G157C | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100162644, COSV59456434; called by muse, mutect2
- ORC4 | c.1310G>C p.*437Sext*2 | Nonstop Mutation (SNP) | VAF 6/73 reads (8%) | catalogued as COSV99605215; called by muse, mutect2
- P2RY13 | c.858G>C p.K286N | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.63); PolyPhen benign (0.021); catalogued as COSV99854906; called by muse, mutect2, varscan2
- PAPOLA | c.1943G>T p.G648V | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.272); catalogued as COSV99354753; called by muse, mutect2, varscan2
- PAQR8 | c.569C>T p.S190F | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100658547, COSV62442959; called by muse, mutect2, varscan2
- PARK7 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100096806; called by muse, mutect2, varscan2
- PCDH15 | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as rs1244912336, COSV100224560; called by muse, mutect2, varscan2
- PCDHB5 | c.317T>G p.F106C | Missense Mutation (SNP) | VAF 42/71 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99169656; called by muse, mutect2, varscan2
- PCF11 | c.1738G>A p.E580K | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as COSV53529616; called by muse, mutect2, varscan2
- PEAK1 | c.2199G>C p.K733N | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as COSV100433483; called by muse, mutect2, varscan2
- PFKP | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.303); catalogued as COSV66900816; called by muse, mutect2, varscan2
- PHKB | c.2468C>T p.S823F | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV54518991; called by muse, mutect2, varscan2
- PITPNM3 | c.2797G>A p.D933N | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.255); catalogued as rs777178487, COSV51470866; called by muse, mutect2, varscan2
- PLEKHA6 | c.372C>A p.H124Q | Missense Mutation (SNP) | VAF 44/175 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.088); catalogued as COSV99692848; called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as COSV100544562; called by muse, mutect2, varscan2
- POLH | c.491-1G>T p.X164_splice | Splice Site (SNP) | VAF 3/49 reads (6%) | catalogued as COSV100947901; called by muse, mutect2
- POLR2I | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV52900022, COSV99387596; called by muse, mutect2, varscan2
- PPCS | c.338C>T p.S113L | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.054); catalogued as rs1364205580, COSV65333748; called by muse, mutect2
- PPM1A | c.347C>T p.S116L | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs756020328, COSV100349509; called by muse, mutect2, varscan2
- PPP1R36 | c.554A>T p.E185V | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV100073071; called by muse, mutect2, varscan2
- PPP2R5E | c.1072C>G p.Q358E | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100518686, COSV100518853, COSV100518891; called by muse, mutect2, varscan2
- PRAG1 | c.2125G>A p.E709K | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.952); catalogued as COSV100422914; called by muse, mutect2, varscan2
- PRKACA | c.544C>T p.Q182* | Nonsense Mutation (SNP) | VAF 8/41 reads (20%) | catalogued as COSV100432335, COSV100432417; called by muse, mutect2, varscan2
- PRR5 | c.787G>A p.V263M (on ENST00000336985 / NM_181333.4; = p.V254M on NM_015366.4) | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs755369530, COSV99135005; called by muse, mutect2, varscan2
- PRUNE1 | c.777C>T p.A259= | Splice Region (SNP) | VAF 9/172 reads (5%) | catalogued as rs1285068760, COSV99640000; called by muse, mutect2
- PSD3 | c.2193C>G p.I731M (on ENST00000440756; = p.I730M on NM_015310.4) | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99676964; called by muse, mutect2, varscan2
- PTDSS1 | c.69G>C p.M23I | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV99750153; called by muse, mutect2, varscan2
- PTPRM | c.3145G>C p.E1049Q | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.876); catalogued as COSV100160872, COSV59859138; called by muse, mutect2, varscan2
- RAB28 | c.304G>C p.E102Q | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.091); catalogued as COSV56541333; called by muse, mutect2, varscan2
- RAB3GAP1 | c.2872C>G p.R958G | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99921854; called by muse, mutect2, varscan2
- RABGGTB | c.180G>A p.M60I | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV100175246; called by muse, mutect2, varscan2
- RABGGTB | c.274G>C p.D92H | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100175248; called by muse, mutect2
- RANBP2 | c.5746C>G p.L1916V | Missense Mutation (SNP) | VAF 51/393 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV99313436; called by muse, mutect2, varscan2
- RASGRF1 | c.3694C>T p.Q1232* | Nonsense Mutation (SNP) | VAF 5/83 reads (6%) | catalogued as COSV101174804; called by muse, mutect2
- RB1 | c.2236G>T p.E746* | Nonsense Mutation (SNP) | VAF 17/28 reads (61%) | catalogued as CM040265, COSV57314725, COSV57323773; called by muse, mutect2, varscan2
- RBMS2 | c.146G>T p.G49V | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as COSV100008716; called by muse, mutect2, varscan2
- RIF1 | c.4427A>C p.E1476A | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.141); catalogued as COSV54622058, COSV99691324; called by muse, mutect2, varscan2
- RPL23A | c.87G>C p.L29F | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV99411904; called by muse, mutect2
- RPS6KA1 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as COSV100838004; called by muse, mutect2
- RUNDC3A | c.985C>G p.L329V | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.041); catalogued as rs779213235, COSV99835437; called by muse, mutect2, varscan2
- SEC23B | c.1393G>A p.V465I | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0.013); catalogued as rs745421570, COSV99358130; called by mutect2, varscan2
- SEPHS1 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 48/284 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.682); catalogued as COSV100526049, COSV59259099; called by muse, varscan2
- SETX | c.5227T>C p.Y1743H | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99811110; called by muse, mutect2, varscan2
- SGIP1 | c.170C>A p.S57* | Nonsense Mutation (SNP) | VAF 3/21 reads (14%) | catalogued as COSV52766669, COSV99393086; called by muse, mutect2
- SGK1 | c.674C>A p.P225Q | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99399242; called by muse, mutect2, varscan2
- SIPA1L1 | c.872G>C p.G291A | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (1); PolyPhen probably damaging (0.995); catalogued as COSV100666122; called by muse, mutect2, varscan2
- SKP2 | c.608C>T p.S203F | Missense Mutation (SNP) | VAF 11/227 reads (5%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.81); catalogued as COSV99948328; called by muse, mutect2
- SLCO4C1 | c.856G>A p.G286R | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs573882552, COSV100195174; called by muse, mutect2, varscan2
- SNAP91 | c.2038C>T p.P680S | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.374); catalogued as COSV99536772; called by muse, mutect2
- SRCAP | c.9290C>T p.A3097V | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as COSV99351447; called by muse, mutect2, varscan2
- SRSF1 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as COSV99365494; called by muse, mutect2, varscan2
- SRSF6 | c.127G>C p.E43Q | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); catalogued as rs1216408495, COSV99719855; called by muse, mutect2, varscan2
- STAT3 | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); catalogued as COSV99233298; called by muse, mutect2
- STK31 | c.690A>T p.Q230H | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as COSV100669998; called by muse, mutect2, varscan2
- SYT2 | c.1177G>A p.A393T | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.194); catalogued as COSV100937220; called by muse, mutect2, varscan2
- TBC1D17 | c.198C>G p.D66E | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV99680967; called by muse, mutect2, varscan2
- TBC1D9 | c.856C>G p.L286V | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as COSV101464412; called by muse, mutect2
- TCHH | c.4093G>A p.E1365K | Missense Mutation (SNP) | VAF 34/426 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.075); catalogued as COSV100915529; called by muse, mutect2
- TEX14 | c.3826G>C p.E1276Q (on ENST00000240361 / NM_001201457.2; = p.E1230Q on NM_031272.5) | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as COSV99543768; called by muse, mutect2, varscan2
- TEX45 | c.1160C>T p.A387V | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.358); catalogued as rs975885488, COSV100861831; called by muse, mutect2
- TGOLN2 | c.1183C>G p.L395V | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV99965160; called by muse, mutect2
- THY1 | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs11546392, COSV99411610; called by muse, mutect2, varscan2
- TMEM92 | c.369G>A p.V123= | Splice Region (SNP) | VAF 10/171 reads (6%) | catalogued as COSV100305240; called by muse, mutect2
- TNS3 | c.3298G>A p.E1100K | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV100236536; called by muse, mutect2, varscan2
- TPT1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 9/12 reads (75%) | SIFT deleterious (0.05); PolyPhen benign (0.133); catalogued as rs1255119916, COSV100496034, COSV58539175; called by muse, mutect2, varscan2
- TRIO | c.7064C>G p.S2355C | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.99); catalogued as rs777447174, COSV100702744; called by muse, varscan2
- TRIP11 | c.2650G>A p.D884N | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.102); catalogued as COSV99971254; called by muse, mutect2
- TTBK2 | c.2913G>C p.K971N | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV99142546; called by muse, mutect2, varscan2
- TTBK2 | c.2659G>A p.E887K | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.112); catalogued as COSV99142550; called by muse, mutect2, varscan2
- TTBK2 | c.2524G>C p.E842Q | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.494); catalogued as COSV99142190, COSV99142552; called by muse, mutect2, varscan2
- TTC33 | c.44C>T p.S15L | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.84); catalogued as COSV100531851, COSV100532132; called by muse, mutect2, varscan2
- TUBGCP3 | c.1118A>G p.D373G | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.2); catalogued as COSV99997319; called by muse, varscan2
- UIMC1 | c.1355C>G p.S452C | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV101022229; called by muse, mutect2
- UPK3A | c.736C>G p.H246D | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99343234; called by muse, mutect2, varscan2
- USP11 | c.1669G>A p.E557K (on ENST00000218348; = p.E514K on NM_001371072.1) | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as COSV99511210; called by muse, mutect2, varscan2
- USP48 | c.1327G>T p.D443Y | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV100380284; called by muse, mutect2
- VANGL1 | c.1478A>G p.N493S | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.69); PolyPhen benign (0.089); catalogued as rs1247564900, COSV59623242; called by muse, mutect2, varscan2
- VIM | c.23C>T p.S8L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as COSV99813389; called by muse, mutect2, varscan2
- VPS37B | c.124C>T p.Q42* | Nonsense Mutation (SNP) | VAF 11/48 reads (23%) | catalogued as COSV99931788, COSV99932055; called by muse, mutect2, varscan2
- WDHD1 | c.3253C>T p.R1085C | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs779514064, COSV100777661; called by mutect2, varscan2
- WDR36 | c.1561T>C p.Y521H | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1007164205, COSV72605518; called by muse, mutect2
- WRAP73 | c.1358G>T p.C453F | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as rs758148303, COSV99573543; called by muse, mutect2, varscan2
- WWC3 | c.2067C>G p.Y689* | Nonsense Mutation (SNP) | VAF 6/61 reads (10%) | catalogued as COSV101081887; called by muse, mutect2, varscan2
- XIRP2 | c.7498A>G p.I2500V (on ENST00000628543; = p.I2675V on NM_152381.6) | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.011); catalogued as COSV99748014; called by muse, mutect2, varscan2
- XKR4 | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 30/168 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100531009, COSV100534206; called by muse, mutect2, varscan2
- ZBED9 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV101509409; called by muse, mutect2, varscan2
- ZC3H12C | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV99585377; called by muse, mutect2, varscan2
- ZCWPW2 | c.401T>C p.V134A | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV101075367; called by muse, mutect2
- ZNF222 | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.177); catalogued as rs374780710; called by muse, mutect2
- ZNF23 | c.1669G>C p.E557Q | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100612293; called by muse, mutect2, varscan2
- AATF | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.041); called by muse, mutect2
- ACOX1 | c.1259_1260dup p.E421Lfs*8 | Frame Shift Ins (INS) | VAF 30/91 reads (33%) | called by mutect2, pindel, varscan2
- DYNC1H1 | c.9051G>T p.V3017= | Splice Region (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- FGFR3 | c.262del p.L88Wfs*10 | Frame Shift Del (DEL) | VAF 7/27 reads (26%) | called by mutect2, pindel, varscan2
- IGHV4-28 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 21/307 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.165); called by muse, mutect2
- RNF40 | c.2077G>T p.E693* | Nonsense Mutation (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- ZNF563 | c.-7_3del | Translation Start Site (DEL) | VAF 16/118 reads (14%) | called by mutect2, pindel
- ZNF613 | c.1328del p.L443* (on ENST00000293471 / NM_001031721.4; = p.L407* on NM_024840.4) | Frame Shift Del (DEL) | VAF 7/66 reads (11%) | called by mutect2, pindel*
- ABCF2 | c.1509C>T p.Y503= | Silent (SNP) | VAF 18/195 reads (9%) | catalogued as rs750282865, COSV55180959, COSV55182167; called by muse, mutect2
- ADAM21 | c.1821G>A p.V607= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as rs1461279396, COSV99961500; called by muse, mutect2
- ADM | c.531G>A p.P177= | Silent (SNP) | VAF 3/30 reads (10%) | catalogued as rs1294214632, COSV53403772, COSV99534395; called by muse, mutect2
- AHNAK2 | c.10185G>A p.E3395= | Silent (SNP) | VAF 25/316 reads (8%) | catalogued as COSV100319104; called by muse, mutect2
- AK7 | c.54G>A p.Q18= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as rs775049122, COSV99967579; called by muse, mutect2, varscan2
- AKNAD1 | c.1794G>C p.T598= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV100645923; called by mutect2, varscan2
- AMIGO1 | c.1455C>T p.V485= | Silent (SNP) | VAF 7/69 reads (10%) | catalogued as COSV100881050, COSV100881115; called by muse, mutect2
- ARPIN | c.597C>T p.I199= | Silent (SNP) | VAF 10/85 reads (12%) | catalogued as COSV62590625; called by muse, mutect2, varscan2
- ATP5PB | c.51G>A p.L17= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as COSV99330997; called by muse, mutect2, varscan2
- B3GNT6 | c.112C>A p.R38= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs1555027411, COSV100845815; called by muse, mutect2
- CCDC102B | c.930G>A p.V310= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs1408929420, COSV100105047; called by muse, mutect2
- CCDC189 | c.564C>G p.L188= | Silent (SNP) | VAF 6/65 reads (9%) | catalogued as COSV100079863; called by muse, mutect2
- CCDC189 | c.444C>G p.L148= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as COSV100079864; called by muse, mutect2, varscan2
- DLG5 | c.2349C>T p.S783= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV100967922; called by muse, mutect2, varscan2
- DYSF | c.786C>T p.F262= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV99250703; called by muse, mutect2, varscan2
- ELFN2 | c.237G>A p.G79= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV68744843; called by muse, mutect2
- EPS15L1 | c.801G>A p.V267= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as COSV99933777; called by muse, mutect2, varscan2
- FAM207A | c.441C>T p.L147= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV99384212, COSV99384229; called by muse, mutect2, varscan2
- FZD2 | c.1479G>A p.S493= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV100190831; called by muse, mutect2, varscan2
- GLP2R | c.540G>A p.L180= | Silent (SNP) | VAF 14/216 reads (6%) | catalogued as rs780243421, COSV99302008, COSV99302538; called by muse, mutect2
- GTPBP1 | c.204G>A p.V68= | Silent (SNP) | VAF 3/30 reads (10%) | catalogued as COSV53283881; called by muse, mutect2
- H4C9 | c.150C>T p.L50= | Silent (SNP) | VAF 11/79 reads (14%) | catalogued as COSV100574950; called by muse, mutect2, varscan2
- HOXC13 | c.588G>A p.G196= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as rs778942107, COSV99673612; called by muse, mutect2, varscan2
- HRNR | c.1482C>T p.H494= | Silent (SNP) | VAF 42/579 reads (7%) | catalogued as rs77355406; called by muse, mutect2
- IGFL1 | c.270G>A p.L90= | Silent (SNP) | VAF 11/126 reads (9%) | catalogued as rs1268501579, COSV71443626; called by muse, mutect2
- IHO1 | c.798G>A p.V266= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs1244805007, COSV99606640; called by muse, mutect2, varscan2
- IL31 | c.114A>G p.V38= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV100986597; called by muse, mutect2, varscan2
- IL36A | c.333G>A p.Q111= | Silent (SNP) | VAF 7/98 reads (7%) | catalogued as COSV99382135; called by muse, mutect2
- KCNJ9 | c.243G>A p.L81= | Silent (SNP) | VAF 3/25 reads (12%) | catalogued as COSV100927810; called by muse, mutect2
- KLK10 | c.54G>A p.A18= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs763595967, COSV100011319, COSV59397286; called by muse, mutect2, varscan2
- KRT19 | c.1026C>T p.I342= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as COSV99563313; called by muse, mutect2, varscan2
- KTI12 | c.954G>A p.L318= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as COSV100860277; called by muse, mutect2
- MCF2L2 | c.3180A>G p.E1060= | Silent (SNP) | VAF 6/105 reads (6%) | catalogued as COSV100194104; called by muse, mutect2
- MED22 | c.246C>G p.L82= | Silent (SNP) | VAF 4/83 reads (5%) | catalogued as COSV59300977; called by muse, mutect2
- MFSD6L | c.570C>T p.V190= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV100266931; called by muse, mutect2, varscan2
- MOCS1 | c.138G>A p.R46= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV100418879; called by muse, mutect2, varscan2
- MROH8 | c.1338G>A p.Q446= | Silent (SNP) | VAF 14/191 reads (7%) | catalogued as COSV99456948, COSV99458001; called by muse, mutect2
- MTHFD2 | c.258C>T p.L86= | Silent (SNP) | VAF 23/101 reads (23%) | catalogued as COSV99903232; called by muse, mutect2, varscan2
- NUP153 | c.2322T>G p.S774= | Silent (SNP) | VAF 9/91 reads (10%) | catalogued as COSV100020889; called by muse, mutect2
- OR13H1 | c.859C>T p.L287= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as COSV100088419, COSV100088465; called by muse, mutect2, varscan2
- OR13J1 | c.450C>T p.V150= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV100940841; called by muse, mutect2, varscan2
- OR14K1 | c.147G>T p.L49= | Silent (SNP) | VAF 4/84 reads (5%) | catalogued as COSV99315445, COSV99315519; called by muse, mutect2
- OR2T34 | c.198C>T p.F66= | Silent (SNP) | VAF 6/91 reads (7%) | catalogued as COSV100170581; called by muse, varscan2
- OS9 | c.87G>C p.G29= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV99233163; called by muse, mutect2, varscan2
- P2RY2 | c.705C>A p.G235= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV100232878; called by muse, mutect2, varscan2
- PAN3 | c.1863T>C p.I621= | Silent (SNP) | VAF 6/100 reads (6%) | catalogued as COSV99145227; called by muse, mutect2
- PCNT | c.6732G>A p.V2244= | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as COSV100856084; called by muse, mutect2, varscan2
- PIGU | c.378C>T p.L126= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as COSV99466943; called by muse, mutect2, varscan2
- PLA2G7 | c.699C>T p.L233= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as COSV99221627; called by muse, mutect2, varscan2
- POLR1A | c.4968A>G p.P1656= | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as COSV99808523; called by muse, mutect2, varscan2
- PRDX6 | c.483C>T p.L161= | Silent (SNP) | VAF 8/132 reads (6%) | catalogued as rs1158885829, COSV100458583, COSV61165075; called by muse, mutect2
- PTPN21 | c.1914C>T p.I638= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as rs1478633008, COSV100162578; called by muse, mutect2, varscan2
- PTPRM | c.612C>T p.F204= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as COSV100160868; called by muse, mutect2, varscan2
- RASGRF1 | c.1737C>T p.I579= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV101369764; called by muse, mutect2, varscan2
- RBKS | c.450C>A p.V150= | Silent (SNP) | VAF 13/109 reads (12%) | catalogued as COSV100142461, COSV56221939; called by muse, mutect2, varscan2
- RFPL1 | c.810C>T p.F270= | Silent (SNP) | VAF 5/58 reads (9%) | catalogued as rs955567907, COSV100585921; called by muse, mutect2
- RFT1 | c.1152C>T p.I384= | Silent (SNP) | VAF 5/62 reads (8%) | catalogued as COSV99965627; called by muse, mutect2
- RNF135 | c.414G>A p.L138= | Silent (SNP) | VAF 28/78 reads (36%) | catalogued as COSV100104276; called by muse, mutect2, varscan2
- RRS1 | c.30C>T p.L10= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV99398157, COSV99398223; called by muse, mutect2, varscan2
- SETD1A | c.600G>C p.L200= | Silent (SNP) | VAF 13/106 reads (12%) | catalogued as COSV99353772; called by muse, mutect2, varscan2
- SLC25A48 | c.261C>T p.L87= | Silent (SNP) | VAF 6/63 reads (10%) | catalogued as rs141621757, COSV50848559; called by muse, mutect2, varscan2
- SLC26A11 | c.1302C>T p.D434= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs1399937758, COSV100755477; called by muse, mutect2, varscan2
- SLC2A3 | c.954C>T p.F318= | Silent (SNP) | VAF 4/58 reads (7%) | catalogued as COSV99307000; called by muse, mutect2
- SLC9A8 | c.189C>T p.F63= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV100846342; called by muse, mutect2, varscan2
- SPA17 | c.432T>C p.N144= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV99907276; called by muse, mutect2, varscan2
- SPAG17 | c.2463C>T p.V821= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV100310717; called by muse, mutect2, varscan2
- SUN2 | c.1134C>T p.V378= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV99325878; called by muse, mutect2, varscan2
- SYT4 | c.216G>A p.K72= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs374054209, COSV54900119; called by muse, mutect2, varscan2
- TAS2R31 | c.783C>T p.F261= | Silent (SNP) | VAF 20/198 reads (10%) | catalogued as COSV101115681; called by muse, mutect2
- THPO | c.1161G>C p.L387= (on ENST00000649095 / NM_001290003.1; = p.L247= on NM_000460.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 4/84 reads (5%) | catalogued as COSV99201234, COSV99201242; called by muse, mutect2
- TMEM132E | c.477C>T p.T159= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV58698937; called by muse, mutect2
- TPTE | c.681A>G p.K227= (on ENST00000618007 / NM_199261.4; = p.K209= on NM_199259.4) | Silent (SNP) | VAF 15/256 reads (6%) | called by muse, mutect2
- TRIM26 | c.1530C>T p.L510= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV101443945, COSV101443988; called by muse, mutect2, varscan2
- TRIM27 | c.474G>A p.K158= | Silent (SNP) | VAF 7/127 reads (6%) | catalogued as COSV101019483; called by muse, mutect2
- TSHZ3 | c.987G>A p.E329= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as COSV99552909; called by muse, mutect2, varscan2
- TTN | c.40869C>T p.L13623= (on ENST00000591111; = p.L6199= on NM_003319.4) | Silent (SNP) | VAF 12/125 reads (10%) | catalogued as COSV100632488; called by muse, mutect2, varscan2
- UGT2A3 | c.144G>A p.V48= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV52362026; called by muse, mutect2, varscan2
- USP38 | c.417G>A p.P139= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as rs1272072161, COSV100189522; called by muse, mutect2, varscan2
- ZNF337 | c.51C>T p.V17= | Silent (SNP) | VAF 6/98 reads (6%) | catalogued as COSV99430511; called by muse, mutect2
- BTN2A3P | n.1448-10G>A | Intron (SNP) | VAF 9/86 reads (10%) | called by muse, mutect2
- CHCHD2P9 | n.399C>T | RNA (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2, varscan2
- DCHS2 | n.1736C>A | RNA (SNP) | VAF 21/54 reads (39%) | catalogued as COSV100253349; called by muse, mutect2, varscan2
- LAMTOR5 | chr1:110407818 T>G | 5'Flank (SNP) | VAF 5/34 reads (15%) | catalogued as COSV99862209; called by muse, mutect2, varscan2
- NEBL-AS1 | chr10:21173831 C>T | 5'Flank (SNP) | VAF 4/26 reads (15%) | catalogued as COSV101346371; called by muse, mutect2
- RC3H2 | c.961-95G>A | Intron (SNP) | VAF 5/111 reads (5%) | catalogued as COSV100106952, COSV59014913; called by muse, mutect2
- TUBB7P | n.233C>T | RNA (SNP) | VAF 29/77 reads (38%) | catalogued as rs531124571; called by muse, mutect2, varscan2
- UNG | c.133-31C>G | Intron (SNP) | VAF 8/44 reads (18%) | catalogued as COSV54358687; called by muse, mutect2, varscan2
- ZNF271P | n.1603G>A | RNA (SNP) | VAF 10/56 reads (18%) | catalogued as rs757793965; called by muse, mutect2, varscan2
